Somatic mutation profile of tumor specimen TCGA-5P-A9K0-01A (aliquot TCGA-5P-A9K0-01A-11D-A42J-10) from TCGA case TCGA-5P-A9K0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 75.1 years (27,434 days).
Specimen TCGA-5P-A9K0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c2a854e-d048-463b-a337-df88ca36df78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9K0-10A (Blood Derived Normal), aliquot TCGA-5P-A9K0-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1b013f4-effa-461b-86a4-ca682b4b268b

The open-access MAF lists 95 somatic variants for this specimen: 72 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 20, Frame Shift Del 10, In Frame Del 3, Intron 3, Splice Site 2, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABT1 | c.86A>C p.Q29P | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99223113; called by muse, mutect2, varscan2
- ACAA1 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100085847; called by muse, mutect2, varscan2
- ANKRD55 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100591076; called by muse, mutect2, varscan2
- ATP1B4 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 110/140 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs774880830, COSV99486166; called by muse, mutect2, varscan2
- ATP6V1E2 | c.28A>C p.K10Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV100120698; called by muse, mutect2, varscan2
- ATP6V1E2 | c.27A>T p.K9N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100120699; called by muse, mutect2, varscan2
- BMP8B | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as rs763546560, COSV100560187; called by muse, mutect2, varscan2
- C1RL | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV56924876, COSV99864436; called by muse, varscan2
- CCDC171 | c.1056G>C p.E352D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.717); catalogued as COSV52650179; called by muse, mutect2, varscan2
- CDC23 | c.1319G>C p.G440A | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV101203086; called by muse, mutect2, varscan2
- CDH20 | c.2113A>C p.I705L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.411); catalogued as COSV99404449; called by muse, mutect2, varscan2
- CENPB | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV100713313; called by muse, mutect2, varscan2
- CNTNAP5 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101443081, COSV70498010; called by muse, mutect2, varscan2
- COL2A1 | c.1622C>G p.P541R | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100475593; called by muse, mutect2, varscan2
- COMT | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV99258339; called by muse, mutect2, varscan2
- CRTAP | c.81A>C p.Q27H | Missense Mutation (SNP) | VAF 242/530 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1011859541, COSV100310007; called by muse, mutect2, varscan2
- CYP11B1 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as CM1511260, COSV99454582; called by muse, varscan2
- ECM1 | c.708+2T>A p.X236_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100681669; called by muse, mutect2, varscan2
- EGFL7 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100451900; called by muse, mutect2, varscan2
- FAM160A2 | c.2173C>A p.P725T (on ENST00000449352 / NM_001098794.2; = p.P739T on NM_032127.4) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV56410751, COSV99791736; called by muse, mutect2, varscan2
- FAM160B1 | c.1945C>A p.Q649K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100985291; called by muse, mutect2, varscan2
- FANCM | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99950503; called by muse, mutect2, varscan2
- GLUL | c.99del p.I33Mfs*81 | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | catalogued as COSV59381578; called by mutect2, pindel, varscan2
- GRIN2A | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV100408435; called by muse, mutect2, varscan2
- H2AB1 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100371484; called by mutect2, varscan2
- HEBP2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100874932, COSV62928521; called by muse, mutect2, varscan2
- HNRNPLL | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99696435; called by muse, mutect2, varscan2
- HUWE1 | c.3890G>A p.G1297E | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV99470756, COSV99473629; called by muse, mutect2, varscan2
- IQCE | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100383225; called by muse, mutect2, varscan2
- KPNA2 | c.767T>C p.L256S | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100388675; called by muse, mutect2, varscan2
- KRT23 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV99266114; called by muse, mutect2, varscan2
- KRTAP8-1 | c.65del p.P22Rfs*108 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | catalogued as COSV100297872, COSV100297889; called by mutect2, pindel, varscan2
- LRRC66 | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100602838; called by muse, mutect2, varscan2
- MASP1 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1221449152, COSV99396798; called by muse, mutect2, varscan2
- MINPP1 | c.1187A>G p.K396R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV64355997; called by muse, mutect2, varscan2
- MSLNL | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV99557958; called by muse, mutect2, varscan2
- NANOS1 | c.677T>A p.L226H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100403825; called by muse, varscan2
- NHLRC1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs752220824, COSV100513396; called by muse, mutect2, varscan2
- NOL11 | c.584T>G p.L195* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | catalogued as COSV99474844; called by muse, mutect2, varscan2
- OR14C36 | c.659T>G p.F220C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100507388; called by muse, mutect2, varscan2
- PAN3 | c.1080A>T p.R360S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs372499998; called by muse, mutect2, varscan2
- PARP16 | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99975288; called by muse, mutect2, varscan2
- PPP1R3F | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99278446; called by muse, mutect2, varscan2
- PXDC1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100977191; called by muse, mutect2, varscan2
- RAB3A | c.416T>G p.M139R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99717907; called by muse, mutect2, varscan2
- RPN2 | c.1759C>A p.L587M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99411446; called by muse, mutect2, varscan2
- RSPH6A | c.1051A>C p.I351L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99679585; called by muse, mutect2, varscan2
- SEC62 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427891; called by muse, mutect2, varscan2
- SIX6 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 118/327 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100576441; called by muse, mutect2, varscan2
- SLITRK3 | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV99578549; called by muse, mutect2, varscan2
- TANC2 | c.4921G>T p.A1641S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.046); catalogued as COSV101267236; called by muse, mutect2, varscan2
- TBATA | c.885A>C p.E295D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100165127; called by muse, mutect2, varscan2
- TJP3 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs776012616, COSV53662139; called by muse, mutect2, varscan2
- USP4 | c.1375T>G p.L459V | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV99649025; called by muse, mutect2, varscan2
- VIRMA | c.1430T>G p.L477R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99887651; called by muse, mutect2, varscan2
- VPS8 | c.2920T>C p.C974R (on ENST00000625842 / NM_001349294.1; = p.C972R on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs768578913, COSV99800811; called by muse, mutect2, varscan2
- WDR35 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1228498799, COSV99852860; called by muse, mutect2, varscan2
- ZBBX | c.69-2A>T p.X23_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100283178; called by muse, mutect2, varscan2
- ZC3H13 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV99667532; called by muse, mutect2, varscan2
- BCL9 | c.474_479del p.H158_G159del | In Frame Del (DEL) | VAF 33/84 reads (39%) | called by mutect2, pindel, varscan2
- DST | c.365del p.N122Ifs*4 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- EPHA5 | c.2165_2167delinsAA p.L722Qfs*18 | Frame Shift Del (DEL) | VAF 29/106 reads (27%) | called by pindel, varscan2*
- FAM184A | c.816del p.F272Lfs*31 | Frame Shift Del (DEL) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- GPSM2 | c.473_479del p.S158Ifs*8 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- KDM6A | c.3845del p.K1282Rfs*10 | Frame Shift Del (DEL) | VAF 59/105 reads (56%) | called by mutect2, pindel, varscan2
- SLC38A8 | c.1089_1091del p.F364del | In Frame Del (DEL) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- TEAD3 | c.1196del p.V399Gfs*45 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- TECRL | c.190dup p.I64Nfs*3 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- TFRC | c.244_245dup p.M82Ifs*2 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- TGFB1I1 | c.644_652del p.L215_R217del (on ENST00000394863 / NM_001042454.3; = p.L198_R200del on NM_015927.4) | In Frame Del (DEL) | VAF 34/70 reads (49%) | called by mutect2, pindel, varscan2
- ZNF470 | c.687del p.K229Nfs*127 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- ZNF575 | c.337_343del p.H113Afs*? | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- DIO2 | c.402T>C p.P134= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV101375823; called by muse, mutect2, varscan2
- DVL3 | c.1536C>T p.S512= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV99490349; called by muse, mutect2, varscan2
- FAM71C | c.186G>T p.V62= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100175655; called by muse, mutect2, varscan2
- IFT88 | c.1731C>G p.P577= (on ENST00000319980 / NM_001318493.2; = p.P568= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100179455; called by muse, mutect2, varscan2
- ITGA11 | c.1920G>A p.Q640= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100240970; called by muse, mutect2, varscan2
- KNDC1 | c.2898C>T p.S966= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV100463449; called by muse, mutect2, varscan2
- MAP2K4 | c.861C>T p.R287= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV100796118; called by muse, mutect2, varscan2
- MORC3 | c.1767A>C p.A589= | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as COSV101264852; called by muse, mutect2, varscan2
- MYO5A | c.909G>A p.K303= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100697334; called by muse, mutect2, varscan2
- NLRC5 | c.4158G>A p.V1386= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV52664674, COSV99346532; called by muse, mutect2, varscan2
- OXER1 | c.574C>T p.L192= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1410677482, COSV99685254; called by muse, mutect2, varscan2
- PCDHAC1 | c.2358G>T p.G786= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV99165085; called by muse, mutect2
- PGC | c.1020C>T p.N340= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs751954837, COSV100025984; called by muse, mutect2, varscan2
- PIK3CD | c.1899G>A p.L633= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100739984; called by muse, mutect2, varscan2
- RBM15B | c.2460T>C p.L820= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100081921; called by muse, mutect2, varscan2
- SF3B1 | c.1209A>G p.E403= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1172980505, COSV100133880; called by muse, mutect2, varscan2
- SLC5A5 | c.693C>A p.L231= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV55831630; called by muse, mutect2, varscan2
- SLC9A3 | c.978C>T p.N326= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV99375692; called by muse, mutect2, varscan2
- TNS1 | c.3507T>C p.A1169= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99409891; called by muse, mutect2
- ZNF470 | c.682T>C p.L228= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs1231530099; called by mutect2, varscan2
- FAM114A1 | c.-158+250T>C | Intron (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100729178; called by muse, mutect2, varscan2
- NRXN2 | c.3403+5515C>T | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99632618; called by muse, mutect2, varscan2
- TAF1 | c.5002-307A>G | Intron (SNP) | VAF 12/16 reads (75%) | catalogued as COSV99334571; called by muse, mutect2, varscan2
